Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1M8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1M8-01A (Primary Tumor).

ICD-0.3
Carcinoma, Squamous cell, NOS 8070/3
Site: Cervix, NOS C53.9 2/24/11 Jw

SURGICAL PATHOLOGY RE

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED]

Service: Gynecology
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

UTERUS, RADICAL HYSTERECTOMY

- SQUAMOUS CELL CARCINOMA OF THE CERVIX, MODERATELY DIFFERENTIATED, INVASIVE TO MAXIMUM DEPTH OF 0.9 CM (CERVICAL THICKNESS 1.2 CM), MARGINS NOT INVOLVED
- PROLIFERATIVE ENDOMETRIUM
- ADENOMYOSIS
- ENDOSALPINGIOSIS
- SEROSAL SURFACE ADHESIONS
- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY

OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO OOPHORECTOMY

- TUBOOVARIAN ADHESIONS
- HYDROSALPINX

FALLOPIAN TUBE, LEFT, SALPINGECTOMY

- ENDOSALPINGIOSIS

LYMPH NODE, EXTERNAL ILIAC, LEFT, EXCISION

- NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODE, OBTURATOR, LEFT, EXCISION

- NO EVIDENCE OF MALIGNANCY (3/3)

LYMPH NODE, EXTERNAL ILIAC, RIGHT, EXCISION

- NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODE, OBTURATOR, RIGHT, EXCISION

- NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODE, PERIAORTIC, RIGHT, EXCISION

- NO EVIDENCE OF MALIGNANCY (2/2)

LYMPH NODE, PERIAORTIC, LEFT, EXCISION

- NO EVIDENCE OF MALIGNANCY (1/1)

Case is (1, include):		

Source: NCI Genomic Data Commons file 1bfc08e8-8d8e-48d5-933c-916de1137778 (TCGA-C5-A1M8.7EC6DEFF-B0FC-45FF-9B45-92714D5EDBEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).